Surgical pathology report (de-identified scan), TCGA case TCGA-85-8288, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8288-01A (Primary Tumor).

[page 1 of 6]
[REDACTED]

[REDACTED]

[REDACTED]		Case ID	Gross Description
[REDACTED]		[REDACTED]	

[page 2 of 6]
Microscopic Description	Diagnosis Details

[page 3 of 6]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Pulmonectomy Tumor site: Lung Tumor size: 3 x 2 x 2 cm Histologic type: Squamous cell carcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 3/6 positive for metastasis (Intrathoracical 3/6) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- middle

[page 4 of 6]
Laterality		ID
	Right- middle	

[page 5 of 6]
Excision date				Case ID

Source: NCI Genomic Data Commons file 98b9b06b-90ab-4d5a-ae74-c8c7c31715ec (TCGA-85-8288.845E1733-B5FD-4B4B-893B-8F07C9030184.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).